Somatic mutation profile of tumor specimen TCGA-49-AAR2-01A (aliquot TCGA-49-AAR2-01A-11D-A397-08) from TCGA case TCGA-49-AAR2, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 64.3 years (23,479 days).
Specimen TCGA-49-AAR2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aa17d1ba-3fa8-4679-b700-3e7a8bf7f45b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-49-AAR2-11A (Solid Tissue Normal), aliquot TCGA-49-AAR2-11A-11D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f30cf5c-d490-4bd2-bad1-37e18979888a

The open-access MAF lists 427 somatic variants for this specimen: 331 protein-altering or splice-affecting, 86 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 280, Silent 86, Nonsense Mutation 29, Frame Shift Del 10, Frame Shift Ins 4, Splice Site 4, RNA 4, Intron 3, 5'Flank 2, Splice Region 2, Nonstop Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AADACL4 | c.790C>A p.R264S | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as COSV100879356, COSV66105839; called by muse, mutect2, varscan2
- ABCA12 | c.2723T>A p.I908N (on ENST00000272895 / NM_173076.3; = p.I590N on NM_015657.3) | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99788502; called by muse, mutect2, varscan2
- ABI3BP | c.184G>T p.G62* | Nonsense Mutation (SNP) | VAF 19/57 reads (33%) | catalogued as COSV52534377, COSV99425510; called by muse, mutect2, varscan2
- ABR | c.127G>T p.G43C | Missense Mutation (SNP) | VAF 30/104 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV100214825; called by muse, mutect2, varscan2
- ACBD6 | c.760C>T p.R254* | Nonsense Mutation (SNP) | VAF 17/47 reads (36%) | catalogued as rs370869949, COSV100852415; called by muse, mutect2, varscan2
- ACOT11 | c.1619A>T p.Q540L | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.107); catalogued as rs1204994284, COSV100156759; called by muse, mutect2, varscan2
- ACSM4 | c.158A>G p.N53S | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101257036; called by muse, mutect2, varscan2
- ACTN1 | c.1129G>T p.G377C | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as COSV99517308; called by muse, mutect2, varscan2
- ADAM32 | c.2045C>A p.T682N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1404327354, COSV101165262; called by muse, mutect2, varscan2
- ADAMTS12 | c.529G>C p.E177Q | Missense Mutation (SNP) | VAF 34/90 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV100710325; called by muse, mutect2, varscan2
- ADAMTS18 | c.1760C>A p.P587H | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.894); catalogued as COSV99271304; called by muse, mutect2, varscan2
- ADAMTS18 | c.647G>T p.G216V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV99271308; called by muse, mutect2, varscan2
- ADAMTS20 | c.2067A>T p.Q689H | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238959; called by muse, mutect2, varscan2
- ADGRG4 | c.1817G>A p.R606Q | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs373699926, COSV54948729; called by muse, mutect2, varscan2
- ADH7 | c.554G>T p.G185V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202236646, COSV52920639, COSV99265070; called by muse, mutect2, varscan2
- AGL | c.3977A>G p.E1326G | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.049); catalogued as COSV99648519; called by mutect2, varscan2
- ALDH1L1 | c.229G>T p.G77W | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs773242742, COSV99856530; called by muse, mutect2, varscan2
- ARMC5 | c.2776G>T p.G926W | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99192336; called by muse, mutect2, varscan2
- ARNTL2 | c.1284G>T p.E428D | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.317); catalogued as COSV99667534; called by muse, mutect2, varscan2
- ASH1L | c.4862C>T p.S1621F | Missense Mutation (SNP) | VAF 40/124 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.191); catalogued as rs141092903, COSV64212643; called by muse, mutect2, varscan2
- ASH2L | c.172G>A p.G58R | Missense Mutation (SNP) | VAF 24/66 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.559); catalogued as rs1222947272, COSV99166931; called by muse, mutect2, varscan2
- ASTN2 | c.962C>G p.T321S | Missense Mutation (SNP) | VAF 38/77 reads (49%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV100524901; called by muse, varscan2
- ASXL3 | c.4372G>A p.G1458R | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.312); catalogued as COSV52479065; called by muse, mutect2, varscan2
- ATOH1 | c.902C>A p.A301D | Missense Mutation (SNP) | VAF 27/94 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV100024437, COSV60038520; called by muse, mutect2, varscan2
- ATP1A4 | c.2771G>T p.C924F | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100927448; called by muse, mutect2, varscan2
- BAZ2B | c.2989G>A p.A997T | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as rs1012456236, COSV99680870; called by muse, mutect2, varscan2
- BBX | c.1888A>T p.T630S | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100361077; called by muse, mutect2, varscan2
- BET1L | c.231G>T p.M77I | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.021); catalogued as COSV100254721; called by muse, mutect2, varscan2
- BRINP1 | c.1237T>A p.C413S | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs1225445323, COSV99774508; called by muse, mutect2, varscan2
- C8B | c.746C>A p.A249E | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1332870010, COSV100980700; called by muse, mutect2, varscan2
- CACNA1C | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs750835733, CM129870, CM135620, COSV100215664; ClinVar: pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- CALHM5 | c.236G>C p.G79A | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100635520; called by muse, mutect2, varscan2
- CANX | c.349G>C p.D117H | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99910245; called by muse, mutect2, varscan2
- CCDC146 | c.2111G>A p.R704K | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.62); PolyPhen benign (0.005); catalogued as rs1410033460, COSV99592184; called by muse, mutect2, varscan2
- CCDC63 | c.817del p.R273Afs*39 | Frame Shift Del (DEL) | VAF 10/28 reads (36%) | catalogued as COSV57529444; called by mutect2, varscan2
- CCDC73 | c.134G>T p.R45M | Missense Mutation (SNP) | VAF 44/169 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100066530; called by muse, mutect2, varscan2
- CCN3 | c.680G>T p.R227L | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs141834767, COSV99422738; called by muse, mutect2, varscan2
- CD36 | c.514G>T p.V172F | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.203); catalogued as COSV99987195; called by muse, mutect2, varscan2
- CDC42BPB | c.669G>T p.L223F | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100775217; called by muse, mutect2, varscan2
- CDH10 | c.746T>C p.L249S | Missense Mutation (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774016877, COSV100050181, COSV100050794; called by muse, mutect2, varscan2
- CDH2 | c.715G>T p.A239S | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.958); catalogued as COSV104393691, COSV99295804; called by muse, mutect2, varscan2
- CDK1 | c.170A>T p.E57V | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100358769; called by muse, mutect2, varscan2
- CELF4 | c.1030C>A p.L344I | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV100611153; called by muse, mutect2, varscan2
- CEP41 | c.53C>T p.P18L | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as rs111688621, COSV99782581; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CERS3 | c.1047G>T p.E349D | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1334504967, COSV99431310; called by muse, mutect2, varscan2
- CHRM2 | c.1148A>T p.K383M | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100280770; called by muse, mutect2, varscan2
- CHRM3 | c.456C>G p.S152R | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99697591; called by muse, mutect2, varscan2
- CHRM5 | c.461C>A p.A154D | Missense Mutation (SNP) | VAF 32/88 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101271842; called by muse, mutect2, varscan2
- CHST2 | c.1069C>A p.R357S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs1356317574, COSV100535824, COSV100535855, COSV58887289; called by muse, mutect2, varscan2
- CLCA2 | c.602C>A p.T201K | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.475); catalogued as COSV100991369; called by muse, mutect2, varscan2
- COL2A1 | c.580G>A p.A194T | Missense Mutation (SNP) | VAF 108/348 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as rs371445823; called by muse, mutect2, varscan2
- CPED1 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV100120042; called by muse, mutect2, varscan2
- CPNE1 | c.516G>T p.W172C (on ENST00000352393; = p.W177C on NM_003915.5) | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1287905989, COSV100467029; called by muse, mutect2, varscan2
- CPNE1 | c.515G>T p.W172L (on ENST00000352393; = p.W177L on NM_003915.5) | Missense Mutation (SNP) | VAF 16/66 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV100467031; called by muse, mutect2, varscan2
- CRACD | c.2293G>C p.G765R | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV99948623; called by muse, mutect2, varscan2
- CRB1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 13/33 reads (39%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); catalogued as COSV66340206, COSV66348134; called by muse, mutect2, varscan2
- CROT | c.1639G>T p.G547C | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100519338; called by muse, mutect2, varscan2
- CRYL1 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV100004163; called by muse, mutect2, varscan2
- CTNNA3 | c.2027A>C p.Q676P | Missense Mutation (SNP) | VAF 35/102 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101041254; called by muse, mutect2, varscan2
- CTNND2 | c.1723C>A p.Q575K | Missense Mutation (SNP) | VAF 75/189 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV100472272; called by muse, mutect2, varscan2
- CUBN | c.9029C>T p.A3010V | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.62); PolyPhen benign (0.023); catalogued as COSV100912097; called by muse, mutect2, varscan2
- CYLC1 | c.1198G>C p.A400P | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.608); catalogued as COSV100254096; called by muse, mutect2, varscan2
- CYP19A1 | c.349G>C p.G117R | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53059516, COSV99547341; called by muse, mutect2, varscan2
- DACH2 | c.1520T>A p.V507D | Missense Mutation (SNP) | VAF 13/16 reads (81%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100912582; called by muse, mutect2, varscan2
- DBI | c.128-1G>T p.X43_splice (on ENST00000355857 / NM_001079862.3; = p.X60_splice on NM_020548.8 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100275769; called by muse, mutect2, varscan2
- DCAF12L2 | c.1300C>A p.H434N | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100758465; called by muse, mutect2, varscan2
- DCAF13 | c.731T>A p.I244N | Missense Mutation (SNP) | VAF 15/81 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as rs372714335, COSV99885037; called by muse, mutect2, varscan2
- DCAF6 | c.1130A>C p.Q377P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.085); catalogued as rs745447512, COSV100393954; called by muse, mutect2, varscan2
- DDX1 | c.991G>T p.D331Y | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.933); catalogued as COSV99245919; called by muse, mutect2, varscan2
- DEFB129 | c.467C>A p.A156D | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99857347; called by muse, mutect2, varscan2
- DGKH | c.1917G>T p.M639I | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as rs1200598403, COSV99818372; called by muse, mutect2
- DIAPH3 | c.682A>C p.K228Q | Missense Mutation (SNP) | VAF 18/44 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV99932829; called by muse, mutect2, varscan2
- DNAH5 | c.8497C>T p.R2833C | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766481283, CM091940, COSV99445459; called by muse, mutect2, varscan2
- DNAH9 | c.6826C>G p.P2276A | Missense Mutation (SNP) | VAF 50/123 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99304297; called by muse, mutect2, varscan2
- DNAH9 | c.8291G>T p.G2764V | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.515); catalogued as COSV99304300; called by muse, mutect2, varscan2
- DNAI1 | c.863G>A p.R288Q | Missense Mutation (SNP) | VAF 41/72 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1434548322, COSV54281149; called by muse, mutect2, varscan2
- DNAJB2 | c.386G>C p.R129P | Missense Mutation (SNP) | VAF 44/96 reads (46%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.901); catalogued as COSV100338843; called by muse, mutect2, varscan2
- DNAJC5B | c.49G>T p.G17* | Nonsense Mutation (SNP) | VAF 26/96 reads (27%) | catalogued as COSV99395448; called by muse, mutect2, varscan2
- DOK6 | c.116C>A p.P39H | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV101234273, COSV66937469; called by muse, mutect2, varscan2
- DR1 | c.52A>G p.I18V | Missense Mutation (SNP) | VAF 52/137 reads (38%) | SIFT tolerated (0.6); PolyPhen benign (0.157); catalogued as COSV100937778; called by muse, varscan2
- DSCAML1 | c.987C>G p.D329E (on ENST00000321322; = p.D269E on NM_020693.4) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.693); catalogued as COSV100354713; called by muse, mutect2
- DTNA | c.1204C>A p.L402I | Missense Mutation (SNP) | VAF 59/119 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as COSV99311059; called by muse, mutect2, varscan2
- DYTN | c.1546A>T p.K516* | Nonsense Mutation (SNP) | VAF 42/117 reads (36%) | catalogued as COSV101510805; called by muse, mutect2, varscan2
- ELF3 | c.592A>G p.T198A | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.058); catalogued as rs879165146, COSV100668624; called by muse, mutect2, varscan2
- ENPP1 | c.900G>C p.W300C | Missense Mutation (SNP) | VAF 16/61 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100719417; called by muse, mutect2, varscan2
- EPHA5 | c.2958C>A p.F986L | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.096); catalogued as COSV56680703, COSV99896424; called by muse, mutect2, varscan2
- EPHB6 | c.352G>T p.G118C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV101235944; called by muse, mutect2, varscan2
- EPS15L1 | c.170G>T p.W57L | Missense Mutation (SNP) | VAF 80/176 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99932724; called by muse, mutect2, varscan2
- FAM180A | c.233A>T p.E78V | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as COSV100647219; called by muse, mutect2, varscan2
- FAT1 | c.9158G>A p.R3053H | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs756123882, COSV101499093; called by muse, mutect2, varscan2
- FAT3 | c.12037G>T p.E4013* | Nonsense Mutation (SNP) | VAF 4/9 reads (44%) | catalogued as rs1476275938, COSV99962325; called by muse, mutect2, varscan2
- FBN1 | c.6899G>A p.G2300E | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100354091; called by muse, mutect2, varscan2
- FBXL16 | c.413C>T p.T138M | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.821); catalogued as rs141455262; called by muse, mutect2, varscan2
- FGA | c.824C>A p.T275N | Missense Mutation (SNP) | VAF 35/99 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.017); catalogued as COSV100120036; called by muse, mutect2, varscan2
- FGFR1 | c.563T>A p.L188Q (on ENST00000447712 / NM_023110.3; = p.L186Q on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100247470; called by muse, mutect2, varscan2
- FKBP5 | c.533G>T p.G178V | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.539); catalogued as COSV100616039; called by muse, mutect2, varscan2
- FMN2 | c.1804G>T p.A602S | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1179649979, COSV100143029; called by muse, mutect2, varscan2
- FNDC1 | c.5090A>G p.Y1697C | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs990281268, COSV99794996; called by muse, mutect2, varscan2
- FNDC3A | c.176-1G>T p.X59_splice (on ENST00000492622 / NM_001079673.2; = p.X3_splice on NM_014923.5) | Splice Site (SNP) | VAF 42/142 reads (30%) | catalogued as COSV101001167; called by muse, mutect2, varscan2
- FRY | c.1570G>C p.V524L | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV100968826; called by muse, mutect2, varscan2
- FYB2 | c.231G>T p.Q77H | Missense Mutation (SNP) | VAF 36/115 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV100599242; called by muse, mutect2, varscan2
- GABRB3 | c.1352G>T p.W451L | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV100158342, COSV54681190; called by muse, mutect2, varscan2
- GCG | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100972731; called by muse, mutect2, varscan2
- GIMAP2 | c.530G>T p.G177V | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.87); catalogued as COSV56235413; called by muse, mutect2, varscan2
- GIMAP6 | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 52/174 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100188098; called by muse, mutect2, varscan2
- GINS3 | c.584C>A p.S195Y | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV100139218; called by muse, mutect2, varscan2
- GJB5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs138854439; called by muse, mutect2, varscan2
- GPM6A | c.194C>A p.A65E | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV54558734, COSV99702799; called by muse, mutect2, varscan2
- GPR141 | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 30/75 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.305); catalogued as rs1230090119, COSV100550233, COSV57732900; called by muse, mutect2, varscan2
- GPR158 | c.113G>T p.R38M | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV100892905; called by muse, mutect2, varscan2
- GPR52 | c.844A>G p.I282V | Missense Mutation (SNP) | VAF 45/162 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0.268); catalogued as COSV99268022; called by muse, mutect2, varscan2
- GPT | c.175C>G p.P59A | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV99477419; called by muse, mutect2, varscan2
- GRM1 | c.2273G>C p.G758A | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as COSV99264232; called by muse, mutect2, varscan2
- GRM6 | c.1363G>T p.G455* | Nonsense Mutation (SNP) | VAF 7/13 reads (54%) | catalogued as rs1347778910, COSV99179460; called by muse, mutect2, varscan2
- GRM8 | c.427A>T p.K143* | Nonsense Mutation (SNP) | VAF 33/86 reads (38%) | catalogued as COSV100280928; called by muse, mutect2, varscan2
- H2AC6 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.435); catalogued as COSV100019758, COSV58417813; called by muse, mutect2, varscan2
- HAUS7 | c.468T>A p.S156R | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.007); catalogued as COSV100443998; called by muse, mutect2, varscan2
- HGSNAT | c.1089G>T p.E363D | Missense Mutation (SNP) | VAF 93/314 reads (30%) | SIFT tolerated (0.19); PolyPhen benign (0.099); catalogued as COSV99925105; called by muse, mutect2, varscan2
- HMCN1 | c.13428A>T p.Q4476H | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV99624482; called by muse, mutect2, varscan2
- HSD3B2 | c.315G>T p.Q105H | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV101027421; called by muse, mutect2, varscan2
- IFI44L | c.1225G>T p.E409* | Nonsense Mutation (SNP) | VAF 36/96 reads (38%) | catalogued as COSV100654884, COSV100655148; called by muse, mutect2, varscan2
- IGHMBP2 | c.2096G>A p.G699E | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV54820627, COSV99661827; called by muse, mutect2, varscan2
- IGSF10 | c.4072C>A p.P1358T | Missense Mutation (SNP) | VAF 62/170 reads (36%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.563); catalogued as COSV99176719; called by muse, mutect2, varscan2
- IGSF22 | c.1468G>A p.V490M | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.865); catalogued as COSV100079207; called by muse, mutect2, varscan2
- IL20RB | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 15/63 reads (24%) | SIFT tolerated (0.48); PolyPhen benign (0.034); catalogued as rs776564185, COSV100290941; called by muse, mutect2, varscan2
- INSL6 | c.33G>A p.W11* | Nonsense Mutation (SNP) | VAF 7/14 reads (50%) | catalogued as COSV101068436; called by muse, mutect2, varscan2
- INSRR | c.3758C>A p.S1253Y | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as COSV100947168; called by muse, mutect2, varscan2
- IRF6 | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV100883883; called by muse, mutect2, varscan2
- ITPRID2 | c.863G>T p.R288L | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100237911; called by muse, mutect2, varscan2
- KCNB1 | c.1417G>A p.G473S | Missense Mutation (SNP) | VAF 34/124 reads (27%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as rs1338478676, COSV100870390; called by muse, mutect2, varscan2
- KCNH4 | c.564G>T p.Q188H | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.719); catalogued as COSV99236794; called by muse, mutect2, varscan2
- KCNH8 | c.1648T>A p.S550T | Missense Mutation (SNP) | VAF 45/89 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV100108614; called by muse, mutect2, varscan2
- KCNN4 | c.1213G>T p.A405S | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.67); PolyPhen benign (0.024); catalogued as COSV99486940; called by muse, mutect2, varscan2
- KCNT2 | c.3166G>T p.V1056L | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.167); catalogued as COSV54078440; called by muse, mutect2, varscan2
- KDM6B | c.2794G>A p.A932T | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1161540052, COSV99640780; called by muse, mutect2, varscan2
- KEAP1 | c.811G>T p.V271L | Missense Mutation (SNP) | VAF 18/34 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.636); catalogued as COSV50263782, COSV50281859; called by muse, mutect2, varscan2
- KIAA0319 | c.1423G>T p.G475W | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100985224, COSV100985589; called by muse, mutect2, varscan2
- KIAA1549L | c.4874A>T p.Y1625F (on ENST00000321505; = p.Y1922F on NM_012194.3) | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated (0.25); PolyPhen benign (0.381); catalogued as COSV100380933; called by muse, mutect2, varscan2
- KIF13B | c.2785G>T p.E929* | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | catalogued as rs1372952252, COSV101580538; called by muse, mutect2
- KIF2B | c.1036G>T p.E346* | Nonsense Mutation (SNP) | VAF 28/100 reads (28%) | catalogued as COSV99274741; called by muse, mutect2, varscan2
- KLK1 | c.21C>A p.C7* | Nonsense Mutation (SNP) | VAF 10/19 reads (53%) | catalogued as COSV100032530; called by muse, mutect2, varscan2
- KLRC1 | c.576G>T p.L192F | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as rs1475658306, COSV100760738; called by muse, mutect2, varscan2
- KRT31 | c.203C>A p.A68D | Missense Mutation (SNP) | VAF 24/112 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52436223, COSV99289418; called by muse, mutect2, varscan2
- KRTAP21-1 | c.206C>A p.P69Q | Missense Mutation (SNP) | VAF 33/72 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.976); catalogued as COSV100624903; called by muse, mutect2, varscan2
- L1CAM | c.2111C>T p.S704F | Missense Mutation (SNP) | VAF 54/76 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100648878; called by muse, mutect2, varscan2
- LASP1 | c.193G>T p.V65L | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.712); catalogued as COSV100530311; called by muse, mutect2, varscan2
- LEF1 | c.980C>A p.A327E | Missense Mutation (SNP) | VAF 90/286 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99489267; called by muse, mutect2, varscan2
- LGR5 | c.389C>A p.P130H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99877544; called by muse, mutect2, varscan2
- LILRA6 | c.853C>A p.P285T | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); catalogued as COSV99557155; called by muse, varscan2
- LILRB4 | c.1309C>A p.P437T (on ENST00000391733 / NM_001278428.3; = p.P436T on NM_001278426.3) | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0.05); PolyPhen benign (0.046); catalogued as COSV54407531, COSV54408605; called by muse, mutect2, varscan2
- LIM2 | c.124C>A p.L42M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99702229; called by muse, mutect2, varscan2
- LRGUK | c.1372G>T p.G458W | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV99603689; called by muse, varscan2
- LRP1 | c.9929G>T p.G3310V | Missense Mutation (SNP) | VAF 25/79 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.834); catalogued as rs369454885, COSV54523515, COSV99674581; called by muse, mutect2, varscan2
- LRRC66 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV100602836; called by muse, mutect2, varscan2
- LRRIQ1 | c.4601T>C p.L1534P | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs1222226888, COSV101279549; called by muse, mutect2, varscan2
- LYST | c.5096G>T p.C1699F | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.779); catalogued as COSV101088304; called by muse, mutect2, varscan2
- LYZL1 | c.473G>T p.C158F (on ENST00000375500; = p.C112F on NM_032517.6) | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100973599; called by muse, mutect2, varscan2
- LZTR1 | c.2070-2A>T p.X690_splice | Splice Site (SNP) | VAF 25/47 reads (53%) | catalogued as COSV99301338; called by muse, mutect2, varscan2
- MAP3K19 | c.1549A>T p.S517C | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100208114; called by muse, mutect2, varscan2
- MARCHF1 | c.199C>A p.Q67K (on ENST00000274056; = p.Q50K on NM_017923.4) | Missense Mutation (SNP) | VAF 18/75 reads (24%) | SIFT tolerated (0.81); PolyPhen benign (0.003); catalogued as rs1428426460, COSV99920058; called by muse, mutect2, varscan2
- MARCHF1 | c.198C>A p.S66R (on ENST00000274056; = p.S49R on NM_017923.4) | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV56834618; called by muse, mutect2, varscan2
- MARCHF7 | c.574A>T p.S192C | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as COSV99373525; called by muse, mutect2, varscan2
- MEGF10 | c.691G>A p.G231S | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99174725; called by muse, mutect2, varscan2
- MEOX2 | c.182C>A p.A61D | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as COSV100011940; called by muse, varscan2
- MFAP1 | c.1193A>C p.D398A | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99979634; called by muse, mutect2, varscan2
- MLIP | c.1199C>A p.P400Q | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as COSV99228561; called by muse, mutect2, varscan2
- MLKL | c.1337A>T p.D446V | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.342); catalogued as rs779745242, COSV100087205; called by muse, mutect2, varscan2
- MMRN1 | c.1112T>A p.F371Y | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.715); catalogued as COSV53342123; called by muse, mutect2, varscan2
- MRPL15 | c.832G>T p.A278S | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.62); PolyPhen benign (0.001); catalogued as COSV99477497; called by muse, mutect2, varscan2
- MTREX | c.681G>T p.M227I | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100043552; called by muse, mutect2, varscan2
- MUC13 | c.1186C>A p.Q396K | Missense Mutation (SNP) | VAF 31/110 reads (28%) | SIFT tolerated (0.97); PolyPhen benign (0.011); catalogued as COSV100222233; called by muse, mutect2, varscan2
- MUC13 | c.1185C>A p.Y395* | Nonsense Mutation (SNP) | VAF 31/107 reads (29%) | catalogued as COSV100222234; called by muse, mutect2, varscan2
- MUC17 | c.7472C>G p.T2491S | Missense Mutation (SNP) | VAF 101/352 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.063); catalogued as COSV100071746, COSV60296588; called by muse, mutect2, varscan2
- MYO7B | c.5351C>A p.P1784Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200995259, COSV101267802, COSV101267817, COSV101267898; called by muse, mutect2, varscan2
- NAALAD2 | c.586G>T p.G196* | Nonsense Mutation (SNP) | VAF 16/55 reads (29%) | catalogued as COSV100428066; called by muse, mutect2, varscan2
- NDST4 | c.2617T>A p.*873Kext*13 | Nonstop Mutation (SNP) | VAF 24/82 reads (29%) | catalogued as COSV99995557; called by muse, mutect2, varscan2
- NEBL | c.1406T>G p.L469R | Missense Mutation (SNP) | VAF 123/277 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.776); catalogued as COSV101009096; called by muse, mutect2, varscan2
- NEIL3 | c.262G>T p.G88* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV99220016; called by muse, varscan2
- NETO1 | c.1168C>T p.P390S | Missense Mutation (SNP) | VAF 42/65 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100198243; called by muse, mutect2, varscan2
- NFKBIL1 | c.199C>T p.P67S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.84); PolyPhen probably damaging (0.998); catalogued as COSV100385343; called by muse, mutect2, varscan2
- NIPAL1 | c.447G>C p.L149F | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55007325; called by muse, mutect2, varscan2
- NKD2 | c.756del p.I253Lfs*175 | Frame Shift Del (DEL) | VAF 19/64 reads (30%) | catalogued as COSV99723858; called by mutect2, pindel, varscan2
- NLRP14 | c.2831C>A p.A944E | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV100204596; called by muse, mutect2, varscan2
- NME8 | c.785T>A p.V262D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99552849; called by muse, mutect2, varscan2
- NOS3 | c.2006C>A p.T669K | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.999); catalogued as COSV52493956, COSV99871255; called by muse, mutect2
- NPAS3 | c.1385C>G p.S462C (on ENST00000356141 / NM_001164749.2; = p.S430C on NM_022123.3) | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs932333814, COSV100639685, COSV100639845; called by muse, mutect2, varscan2
- NRG3 | c.1746G>T p.L582F (on ENST00000404547 / NM_001370084.1; = p.L558F on NM_001010848.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/191 reads (32%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.893); catalogued as COSV100930769, COSV64557849; called by muse, mutect2, varscan2
- OBI1 | c.1618G>T p.E540* | Nonsense Mutation (SNP) | VAF 47/152 reads (31%) | catalogued as COSV99932291; called by muse, mutect2, varscan2
- OBSCN | c.6652G>T p.A2218S | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.081); catalogued as COSV99473269; called by muse, mutect2, varscan2
- OPCML | c.194G>T p.R65L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100098179, COSV59418118; called by muse, mutect2, varscan2
- OR10A5 | c.897G>T p.K299N | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV100203373; called by muse, mutect2, varscan2
- OR14A16 | c.190C>A p.L64I | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1476094785, COSV62926087; called by muse, mutect2, varscan2
- OR2AK2 | c.245C>G p.A82G | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.012); catalogued as COSV100823178; called by muse, mutect2, varscan2
- OR2G3 | c.868T>A p.Y290N | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100180487; called by muse, mutect2, varscan2
- OR2L13 | c.239T>A p.M80K | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as COSV100813680; called by muse, mutect2, varscan2
- OR4K13 | c.566G>T p.C189F | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV59858886; called by muse, mutect2, varscan2
- OR4K13 | c.275T>A p.I92N | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100237643; called by muse, mutect2, varscan2
- OR51A7 | c.381C>A p.H127Q | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.125); catalogued as COSV100834593; called by muse, mutect2, varscan2
- OR51B6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 12/46 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100970665; called by mutect2, varscan2
- OR51E2 | c.26C>A p.A9D | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV101211315; called by muse, mutect2, varscan2
- OR5D13 | c.521C>A p.T174N | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV100686739; called by muse, mutect2, varscan2
- OR5H14 | c.492C>A p.F164L | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV101454076, COSV71193597; called by muse, mutect2, varscan2
- OR5K4 | c.916A>G p.N306D | Missense Mutation (SNP) | VAF 49/146 reads (34%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.048); catalogued as COSV100721300; called by muse, mutect2, varscan2
- OR6F1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 18/59 reads (31%) | catalogued as COSV100128971, COSV57467462; called by muse, mutect2, varscan2
- OR6F1 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 30/93 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.796); catalogued as COSV100128972; called by muse, mutect2, varscan2
- OR8I2 | c.483G>T p.W161C | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs555731227, COSV100135863; called by muse, mutect2, varscan2
- OR9A4 | c.395A>G p.Y132C | Missense Mutation (SNP) | VAF 40/138 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.951); catalogued as COSV101516343; called by muse, mutect2, varscan2
- P2RY10 | c.547G>C p.A183P | Missense Mutation (SNP) | VAF 20/34 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as COSV99408955; called by muse, mutect2, varscan2
- PAPPA2 | c.4443G>T p.E1481D | Missense Mutation (SNP) | VAF 42/120 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV100867604; called by muse, mutect2, varscan2
- PAQR9 | c.803G>C p.G268A | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as COSV100503695; called by muse, mutect2, varscan2
- PCDH11X | c.1487G>T p.G496V | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1350333573, COSV100008561; called by muse, mutect2, varscan2
- PCDH7 | c.2531C>A p.S844Y | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.196); catalogued as COSV100687583, COSV100688503; called by mutect2, varscan2
- PCDHA1 | c.1498G>T p.G500C | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100974267; called by muse, mutect2, varscan2
- PCDHGA9 | c.1082C>A p.P361H | Missense Mutation (SNP) | VAF 26/35 reads (74%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.951); catalogued as COSV99531472; called by muse, mutect2, varscan2
- PCLO | c.15367G>T p.D5123Y | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100427722; called by muse, mutect2, varscan2
- PCLO | c.7369G>C p.D2457H | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.726); catalogued as COSV100427725; called by muse, mutect2
- PDCD11 | c.779C>G p.S260* | Nonsense Mutation (SNP) | VAF 30/77 reads (39%) | catalogued as COSV100874239, COSV100874243, COSV100874365; called by muse, mutect2, varscan2
- PDE3A | c.1108G>T p.V370L | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); catalogued as COSV100761712, COSV100762646; called by muse, mutect2, varscan2
- PDE3B | c.2476C>A p.P826T | Missense Mutation (SNP) | VAF 36/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56389447, COSV99962032; called by muse, mutect2, varscan2
- PDHA2 | c.313G>C p.G105R | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54777097, COSV99756520; called by muse, mutect2, varscan2
- PDPK1 | c.1520A>C p.E507A | Missense Mutation (SNP) | VAF 32/86 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV99239113; called by muse, mutect2, varscan2
- PGBD1 | c.467G>T p.C156F | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.033); catalogued as COSV99459759; called by muse, mutect2, varscan2
- PHYHIPL | c.573C>A p.H191Q | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100874164; called by muse, mutect2, varscan2
- PLCL1 | c.2398G>T p.D800Y | Missense Mutation (SNP) | VAF 32/117 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101406800; called by muse, mutect2, varscan2
- PLCL1 | c.3095C>T p.T1032I | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs1359157008, COSV101406801, COSV70867706; called by muse, mutect2
- PLEKHG4 | c.58G>T p.D20Y | Missense Mutation (SNP) | VAF 11/39 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs748895283, COSV100846439; called by muse, mutect2, varscan2
- PLG | c.721C>A p.L241M | Missense Mutation (SNP) | VAF 30/66 reads (45%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.499); catalogued as COSV99804276; called by muse, mutect2, varscan2
- PLSCR1 | c.228G>T p.Q76H | Missense Mutation (SNP) | VAF 31/105 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs560059791; called by muse, mutect2, varscan2
- POPDC3 | c.223G>T p.A75S | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.117); catalogued as rs1321756520, COSV99633401; called by muse, mutect2, varscan2
- PPP3CC | c.1117C>A p.L373M | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.209); catalogued as COSV99251812; called by muse, mutect2, varscan2
- PPRC1 | c.2819dup p.P941Tfs*75 | Frame Shift Ins (INS) | VAF 12/40 reads (30%) | catalogued as rs768056539; called by mutect2, varscan2
- PREPL | c.1479G>T p.E493D | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as COSV99575935; called by muse, mutect2, varscan2
- PROC | c.647A>G p.K216R | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as COSV99300666; called by muse, mutect2, varscan2
- PRRC2C | c.6419G>T p.G2140V (on ENST00000367742; = p.G2138V on NM_015172.4) | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as COSV100144710; called by muse, mutect2, varscan2
- PSKH2 | c.498G>A p.M166I | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.472); catalogued as COSV99404996; called by muse, mutect2, varscan2
- PTPRH | c.2144C>A p.A715D | Missense Mutation (SNP) | VAF 24/69 reads (35%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as COSV99670712, COSV99671642; called by muse, mutect2, varscan2
- PTPRK | c.1862A>T p.Q621L | Missense Mutation (SNP) | VAF 25/67 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV100950427; called by muse, mutect2, varscan2
- PTPRT | c.1946C>T p.P649L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV62037501; called by muse, mutect2, varscan2
- RAD54L | c.247A>G p.K83E | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV100914755; called by muse, mutect2, varscan2
- RCC1L | c.1193G>T p.R398L | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as rs140481718; called by muse, mutect2, varscan2
- REG3G | c.328A>T p.T110S | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.948); catalogued as COSV99709242; called by muse, mutect2, varscan2
- RGL1 | c.1317G>A p.E439= (on ENST00000360851 / NM_001297672.2; = p.E474= on NM_015149.5 and 2 other RefSeq transcripts) | Splice Region (SNP) | VAF 13/49 reads (27%) | catalogued as COSV100486234; called by mutect2, varscan2
- RIMS4 | c.795C>A p.C265* | Nonsense Mutation (SNP) | VAF 23/65 reads (35%) | catalogued as COSV100865072, COSV65719945; called by muse, mutect2, varscan2
- RIT2 | c.70G>A p.V24I | Missense Mutation (SNP) | VAF 25/120 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV99949637; called by muse, mutect2, varscan2
- RP1 | c.949G>T p.D317Y | Missense Mutation (SNP) | VAF 22/50 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99606372; called by muse, mutect2, varscan2
- RPE65 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.614); catalogued as rs1468393625, COSV52016481; called by muse, mutect2, varscan2
- RPTN | c.925C>T p.Q309* | Nonsense Mutation (SNP) | VAF 209/624 reads (33%) | catalogued as COSV100285275; called by muse, mutect2, varscan2
- RYR2 | c.5359C>A p.L1787I | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100768194; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- RYR3 | c.8980G>T p.V2994L (on ENST00000389232; = p.V2995L on NM_001036.6) | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.315); catalogued as COSV101212038; called by muse, mutect2, varscan2
- SAMD9 | c.4040T>A p.L1347H | Missense Mutation (SNP) | VAF 40/134 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101180130; called by muse, mutect2, varscan2
- SCNN1A | c.826G>T p.G276C | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); catalogued as rs759933475, COSV99964528; ClinVar: benign / uncertain significance; called by muse, mutect2, varscan2
- SCYL2 | c.451G>T p.D151Y | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1489098087, COSV100675050; called by muse, mutect2, varscan2
- SDK1 | c.1817G>T p.R606L | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.935); catalogued as rs756180206, COSV101268806; called by mutect2, varscan2
- SDK1 | c.1889G>A p.G630E | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101268807; called by muse, mutect2, varscan2
- SEMA5A | c.2811C>A p.S937R | Missense Mutation (SNP) | VAF 38/90 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.056); catalogued as COSV101227169; called by muse, mutect2, varscan2
- SERPING1 | c.394G>T p.D132Y | Missense Mutation (SNP) | VAF 66/175 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); catalogued as COSV99557836; called by muse, mutect2, varscan2
- SERTAD4 | c.67G>C p.A23P | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV100882587; called by muse, mutect2, varscan2
- SIPA1L2 | c.1555G>T p.E519* | Nonsense Mutation (SNP) | VAF 72/233 reads (31%) | catalogued as COSV99477242; called by muse, mutect2, varscan2
- SKAP2 | c.202G>T p.D68Y | Missense Mutation (SNP) | VAF 18/52 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); catalogued as rs1290845343, COSV100591666; called by muse, mutect2, varscan2
- SLC17A6 | c.947T>C p.I316T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99580823; called by muse, mutect2, varscan2
- SLC22A1 | c.241G>T p.G81C | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61453020; called by muse, mutect2, varscan2
- SLC22A1 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); catalogued as COSV100266441; called by muse, mutect2, varscan2
- SLC22A9 | c.1469T>A p.L490Q | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54166273, COSV99654742; called by muse, mutect2, varscan2
- SLC24A5 | c.1163T>C p.V388A | Missense Mutation (SNP) | VAF 29/79 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV99981224; called by muse, mutect2, varscan2
- SLC2A10 | c.1216G>T p.A406S | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.41); PolyPhen benign (0.015); catalogued as COSV63714649; called by muse, mutect2, varscan2
- SLC32A1 | c.770T>A p.L257H | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99461820; called by muse, mutect2, varscan2
- SLC5A6 | c.544G>T p.A182S | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as rs1397427492, COSV100143056; called by muse, mutect2, varscan2
- SLC8A1 | c.1999A>G p.R667G | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.034); catalogued as COSV100244634; called by muse, mutect2, varscan2
- SLC8A1 | c.1121G>T p.G374V | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100244639; called by muse, mutect2, varscan2
- SLCO4C1 | c.1135A>T p.M379L | Missense Mutation (SNP) | VAF 19/40 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100194518; called by muse, mutect2, varscan2
- SLITRK3 | c.2015C>A p.A672E | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99578548; called by muse, mutect2, varscan2
- SMAD9 | c.976G>C p.E326Q (on ENST00000379826 / NM_001127217.3; = p.E289Q on NM_005905.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/74 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100614445; called by muse, mutect2, varscan2
- SMARCAD1 | c.1256G>A p.R419Q | Missense Mutation (SNP) | VAF 41/120 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100758763; called by muse, mutect2, varscan2
- SMG9 | c.225G>T p.R75= | Splice Region (SNP) | VAF 40/77 reads (52%) | catalogued as COSV54213465; called by muse, mutect2, varscan2
- SMYD1 | c.24C>A p.N8K | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs776264865, COSV70224983, COSV70225498; called by muse, mutect2, varscan2
- SNTG1 | c.1191G>T p.Q397H | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.976); catalogued as COSV52431718, COSV99381551; called by muse, mutect2, varscan2
- SP100 | c.2583G>T p.Q861H | Missense Mutation (SNP) | VAF 20/58 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.195); catalogued as rs1189103427, COSV100413539; called by muse, mutect2, varscan2
- SPACA3 | c.485G>T p.C162F | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1423375814, COSV99284110; called by muse, mutect2, varscan2
- SPAG11B | c.65C>T p.S22L | Missense Mutation (SNP) | VAF 14/115 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.025); catalogued as rs758891774, COSV52499535; called by muse, mutect2, varscan2
- SPHKAP | c.3418G>A p.E1140K | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60869316; called by muse, mutect2, varscan2
- SPTA1 | c.1155G>A p.W385* | Nonsense Mutation (SNP) | VAF 48/123 reads (39%) | catalogued as COSV100934334, COSV63748410; called by muse, mutect2, varscan2
- STAB2 | c.3277C>A p.H1093N | Missense Mutation (SNP) | VAF 23/51 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.258); catalogued as COSV101185650; called by muse, mutect2, varscan2
- STATH | c.30G>T p.L10F | Missense Mutation (SNP) | VAF 52/148 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.798); catalogued as rs1286298791, COSV99887152; called by muse, mutect2, varscan2
- STYXL2 | c.2833G>T p.E945* | Nonsense Mutation (SNP) | VAF 7/15 reads (47%) | catalogued as COSV99608621, COSV99609974; called by muse, mutect2, varscan2
- TBL1XR1 | c.142G>T p.A48S | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.925); catalogued as COSV61792178; called by muse, mutect2, varscan2
- TDRD5 | c.23A>C p.Q8P | Missense Mutation (SNP) | VAF 28/92 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.773); catalogued as COSV99675549; called by muse, mutect2, varscan2
- TDRD6 | c.1249C>T p.H417Y | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs777197011, COSV60180160; called by muse, mutect2, varscan2
- TECRL | c.457G>A p.G153R | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV101168487; called by muse, mutect2, varscan2
- TIGD3 | c.422T>C p.L141P | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV99361357; called by muse, mutect2, varscan2
- TNKS2 | c.2694+1G>T p.X898_splice | Splice Site (SNP) | VAF 9/43 reads (21%) | catalogued as COSV100861002; called by muse, mutect2, varscan2
- TNS4 | c.391G>T p.A131S | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.4); PolyPhen benign (0.015); catalogued as COSV99563573; called by muse, mutect2, varscan2
- TRAV14DV4 | c.247C>A p.R83S | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as rs1266640780; called by muse, mutect2, varscan2
- TRIM6 | c.1392T>A p.F464L | Missense Mutation (SNP) | VAF 41/144 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as COSV99546193; called by muse, mutect2, varscan2
- UGGT2 | c.2579G>T p.C860F | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.887); catalogued as rs1425525775, COSV100948489; called by muse, mutect2, varscan2
- UGT2A1 | c.376T>A p.C126S | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99683871; called by muse, mutect2, varscan2
- UGT2B28 | c.1464C>A p.Y488* | Nonsense Mutation (SNP) | VAF 23/108 reads (21%) | catalogued as COSV100158568; called by muse, mutect2, varscan2
- UNC5D | c.1378C>A p.L460M | Missense Mutation (SNP) | VAF 21/48 reads (44%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.459); catalogued as COSV99772410; called by muse, mutect2, varscan2
- VGLL3 | c.572A>T p.N191I | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT tolerated (0.2); PolyPhen benign (0.006); catalogued as COSV101051864; called by muse, mutect2, varscan2
- VNN2 | c.836T>C p.I279T | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV100426704; called by muse, mutect2, varscan2
- VPS45 | c.1019G>T p.R340L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as COSV100964860; called by muse, mutect2, varscan2
- WDR49 | c.622T>A p.L208M (on ENST00000308378 / NM_001366158.1; = p.L549M on NM_001348951.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100391778, COSV57702460; called by muse, mutect2, varscan2
- WDR53 | c.815G>A p.S272N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV100218018; called by muse, mutect2, varscan2
- ZAN | c.5656G>A p.E1886K | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.15); PolyPhen benign (0.12); catalogued as COSV100769218; called by muse, mutect2, varscan2
- ZCCHC17 | c.550A>T p.R184* | Nonsense Mutation (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100703823; called by muse, mutect2, varscan2
- ZER1 | c.1466C>T p.T489M | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.172); catalogued as rs908626349, COSV99401853; called by mutect2, varscan2
- ZFHX4 | c.7033G>C p.D2345H | Missense Mutation (SNP) | VAF 27/139 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); catalogued as COSV50500743, COSV99256881; called by muse, mutect2, varscan2
- ZFHX4 | c.8374G>A p.G2792R | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.947); catalogued as rs1324690885, COSV51453652; called by muse, mutect2
- ZFP2 | c.1319G>A p.C440Y | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433110279, COSV100796990; called by muse, mutect2, varscan2
- ZIC1 | c.1194C>G p.S398R | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV99291564; called by muse, mutect2, varscan2
- ZNF19 | c.1262C>G p.A421G | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as COSV99867099; called by muse, mutect2, varscan2
- ZNF19 | c.1261G>A p.A421T | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1457285488, COSV99867101; called by muse, mutect2, varscan2
- ZNF486 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.541); catalogued as COSV100631074, COSV58721114; called by muse, mutect2, varscan2
- ZNF548 | c.642G>T p.E214D | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100277964; called by muse, mutect2, varscan2
- ZNF574 | c.1532G>T p.R511L | Missense Mutation (SNP) | VAF 83/140 reads (59%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV55902798, COSV99725759; called by muse, mutect2, varscan2
- ZNF585A | c.1246G>T p.G416* (on ENST00000292841 / NM_001288800.2; = p.G361* on NM_152655.3) | Nonsense Mutation (SNP) | VAF 39/84 reads (46%) | catalogued as COSV53067149; called by muse, mutect2, varscan2
- ZNF652 | c.964C>G p.H322D | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62948970; called by muse, mutect2, varscan2
- BCL11B | c.1742del p.G581Afs*24 (on ENST00000357195 / NM_001282237.2; = p.G510Afs*24 on NM_022898.3 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel
- GPR179 | c.2000C>A p.S667* (on ENST00000621958; = p.S666* on NM_001004334.4) | Nonsense Mutation (SNP) | VAF 11/27 reads (41%) | called by muse, mutect2, varscan2
- HERC5 | c.944del p.G315Efs*23 | Frame Shift Del (DEL) | VAF 26/114 reads (23%) | called by mutect2, pindel, varscan2
- IGKV1D-13 | c.328dup p.C110Lfs*5 | Frame Shift Ins (INS) | VAF 53/98 reads (54%) | called by mutect2, varscan2
- ITGA11 | c.2836_2848del p.P946Tfs*16 | Frame Shift Del (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel
- KIR3DL3 | c.317G>C p.W106S | Missense Mutation (SNP) | VAF 44/157 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- LIPK | c.740dup p.N247Kfs*20 | Frame Shift Ins (INS) | VAF 31/132 reads (23%) | called by mutect2, pindel, varscan2
- MED12L | c.4348del p.E1450Kfs*13 | Frame Shift Del (DEL) | VAF 4/36 reads (11%) | called by pindel, varscan2
- NUP107 | c.1219dup p.W407Lfs*12 | Frame Shift Ins (INS) | VAF 18/78 reads (23%) | called by pindel, varscan2
- OR6B1 | c.302del p.L101Rfs*35 | Frame Shift Del (DEL) | VAF 44/131 reads (34%) | called by mutect2, pindel, varscan2
- RPL5 | c.284_314del p.Y95Wfs*21 | Frame Shift Del (DEL) | VAF 23/134 reads (17%) | called by mutect2, pindel
- TPR | c.1684del p.E562Kfs*29 | Frame Shift Del (DEL) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- TPTE | c.954C>A p.F318L (on ENST00000618007 / NM_199261.4; = p.F300L on NM_199259.4) | Missense Mutation (SNP) | VAF 34/130 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.26); called by muse, mutect2, varscan2
- ZNF382 | c.1074del p.K359Sfs*186 | Frame Shift Del (DEL) | VAF 21/47 reads (45%) | called by mutect2, pindel, varscan2
- ABCA13 | c.2211G>T p.V737= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as rs1220306699, COSV70051403; called by muse, mutect2, varscan2
- ACTC1 | c.636T>A p.R212= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as COSV99291610; called by muse, mutect2, varscan2
- ADAM12 | c.1794C>T p.A598= | Silent (SNP) | VAF 43/137 reads (31%) | catalogued as rs757974038, COSV64115260; called by muse, mutect2, varscan2
- ADAM32 | c.2046C>A p.T682= | Silent (SNP) | VAF 18/62 reads (29%) | catalogued as COSV101165263; called by muse, mutect2, varscan2
- ADGRG7 | c.1584G>T p.A528= | Silent (SNP) | VAF 63/164 reads (38%) | catalogued as COSV56295163, COSV99840562; called by muse, mutect2, varscan2
- AIFM1 | c.1683C>T p.G561= | Silent (SNP) | VAF 85/130 reads (65%) | catalogued as COSV99780768; called by muse, mutect2, varscan2
- AKAP13 | c.4662C>T p.S1554= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs766774367, COSV100773175; called by muse, mutect2, varscan2
- ANXA10 | c.417C>A p.L139= | Silent (SNP) | VAF 28/101 reads (28%) | catalogued as COSV100828896; called by muse, mutect2, varscan2
- BCL11B | c.2151G>T p.A717= (on ENST00000357195 / NM_001282237.2; = p.A646= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as rs761274858, COSV100595166; called by muse, mutect2
- BNC2 | c.729C>A p.I243= | Silent (SNP) | VAF 18/32 reads (56%) | catalogued as COSV101032234; called by muse, varscan2
- BPIFB6 | c.1173G>T p.S391= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as COSV100848487, COSV100848557; called by muse, mutect2, varscan2
- C8A | c.1407G>T p.R469= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as COSV100776444, COSV63483676; called by muse, mutect2, varscan2
- C8B | c.747A>T p.A249= | Silent (SNP) | VAF 10/50 reads (20%) | catalogued as COSV100980699; called by muse, mutect2, varscan2
- C8orf74 | c.411G>T p.L137= | Silent (SNP) | VAF 56/144 reads (39%) | catalogued as COSV58753479, COSV58755547; called by muse, mutect2, varscan2
- C9orf72 | c.276G>T p.V92= | Silent (SNP) | VAF 17/21 reads (81%) | catalogued as COSV101186487; called by muse, mutect2, varscan2
- CABP2 | c.363G>A p.E121= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as COSV53709112; called by muse, mutect2, varscan2
- CCL13 | c.246C>A p.V82= | Silent (SNP) | VAF 11/23 reads (48%) | catalogued as COSV56774712, COSV99861671; called by muse, mutect2, varscan2
- CD22 | c.1545C>A p.P515= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99322894; called by muse, mutect2, varscan2
- CELSR2 | c.6255G>T p.L2085= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as rs1461115494, COSV99603119; called by muse, mutect2, varscan2
- CHD3 | c.1735C>A p.R579= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV100390760, COSV100391300; called by muse, mutect2, varscan2
- CLCA2 | c.1350C>A p.A450= | Silent (SNP) | VAF 18/70 reads (26%) | catalogued as rs1161207341, COSV100991370; called by muse, mutect2, varscan2
- CRYZ | c.927C>T p.A309= | Silent (SNP) | VAF 40/123 reads (33%) | catalogued as rs148460789; called by muse, mutect2, varscan2
- CSMD3 | c.7794A>G p.R2598= (on ENST00000297405 / NM_001363185.1; = p.R2494= on NM_052900.3) | Silent (SNP) | VAF 32/134 reads (24%) | catalogued as rs1475923778, COSV99825673; called by muse, varscan2
- CYSLTR2 | c.546C>A p.G182= | Silent (SNP) | VAF 34/120 reads (28%) | catalogued as COSV99935128; called by muse, mutect2, varscan2
- DCAF12L2 | c.1299C>A p.T433= | Silent (SNP) | VAF 31/54 reads (57%) | catalogued as COSV100758466, COSV63582683; called by muse, mutect2, varscan2
- DDX1 | c.990G>T p.R330= | Silent (SNP) | VAF 19/67 reads (28%) | catalogued as COSV99245915; called by muse, mutect2, varscan2
- DENND5A | c.1923G>C p.L641= | Silent (SNP) | VAF 39/129 reads (30%) | catalogued as COSV100064105; called by muse, mutect2, varscan2
- DOCK3 | c.1590G>T p.L530= | Silent (SNP) | VAF 7/22 reads (32%) | catalogued as COSV99809332; called by muse, mutect2, varscan2
- DRD1 | c.163C>A p.R55= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1456255665, COSV101192376, COSV67104835; called by muse, mutect2, varscan2
- DRD2 | c.1005C>A p.P335= | Silent (SNP) | VAF 17/39 reads (44%) | catalogued as COSV60760436; called by muse, mutect2, varscan2
- FAM155B | c.1014C>A p.L338= | Silent (SNP) | VAF 7/13 reads (54%) | catalogued as COSV52935582, COSV99368161; called by muse, mutect2, varscan2
- FCRL6 | c.567C>G p.V189= | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV100220044; called by muse, mutect2
- FER1L6 | c.801C>T p.T267= | Silent (SNP) | VAF 103/199 reads (52%) | catalogued as rs967324684, COSV101205494; called by muse, mutect2, varscan2
- FGF23 | c.612C>A p.A204= | Silent (SNP) | VAF 11/34 reads (32%) | catalogued as COSV99426248; called by muse, mutect2, varscan2
- FICD | c.832C>T p.L278= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as COSV99933871, COSV99934385; called by muse, mutect2, varscan2
- GBA | c.1437G>A p.Q479= | Silent (SNP) | VAF 9/34 reads (26%) | catalogued as COSV100516234; called by muse, mutect2, varscan2
- GFM1 | c.180T>C p.T60= | Silent (SNP) | VAF 31/96 reads (32%) | catalogued as COSV99962694; called by muse, mutect2, varscan2
- IGSF22 | c.267G>A p.R89= | Silent (SNP) | VAF 34/123 reads (28%) | catalogued as COSV100079209; called by muse, mutect2, varscan2
- IL21R | c.1575C>A p.V525= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as COSV100559837; called by muse, mutect2, varscan2
- IRX4 | c.657G>T p.R219= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as COSV99180770, COSV99181144; called by muse, varscan2
- ITPRID2 | c.864A>T p.R288= | Silent (SNP) | VAF 11/55 reads (20%) | catalogued as COSV100237914; called by muse, mutect2, varscan2
- JPH3 | c.660G>T p.L220= | Silent (SNP) | VAF 24/80 reads (30%) | catalogued as rs1407594998, COSV99412868; called by muse, mutect2
- KIAA1549L | c.4317C>T p.A1439= (on ENST00000321505; = p.A1736= on NM_012194.3) | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs751434579, COSV100380932; called by muse, mutect2, varscan2
- KLK2 | c.238C>T p.L80= | Silent (SNP) | VAF 11/27 reads (41%) | catalogued as COSV100319842; called by muse, mutect2, varscan2
- LIM2 | c.123C>A p.G41= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as COSV99702231; called by muse, mutect2, varscan2
- LRRC4C | c.778C>A p.R260= | Silent (SNP) | VAF 30/89 reads (34%) | catalogued as COSV53420745, COSV99537061; called by muse, mutect2, varscan2
- MSH4 | c.2265C>A p.L755= | Silent (SNP) | VAF 16/81 reads (20%) | catalogued as rs5745506, COSV99590706; called by muse, mutect2, varscan2
- MTPAP | c.408G>T p.T136= | Silent (SNP) | VAF 62/130 reads (48%) | catalogued as rs763322864, COSV53933142, COSV99553831; called by muse, mutect2, varscan2
- MUC5B | c.3513C>T p.C1171= | Silent (SNP) | VAF 15/63 reads (24%) | catalogued as rs553466241, COSV71593203; called by muse, mutect2, varscan2
- NAIF1 | c.567G>T p.T189= | Silent (SNP) | VAF 32/99 reads (32%) | catalogued as rs761254168, COSV100895715, COSV66090666; called by muse, mutect2, varscan2
- NCOR2 | c.2832C>A p.L944= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as COSV100656904; called by muse, mutect2, varscan2
- NDRG2 | c.456G>T p.L152= (on ENST00000298687 / NM_001354570.1; = p.L138= on NM_016250.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/98 reads (22%) | catalogued as COSV100068905; called by muse, mutect2, varscan2
- NFRKB | c.210C>T p.L70= (on ENST00000446488 / NM_001143835.2; = p.L83= on NM_006165.3) | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV100451794; called by muse, mutect2, varscan2
- NRXN3 | c.1665T>A p.T555= (on ENST00000335750 / NM_001330195.2; = p.T182= on NM_004796.6) | Silent (SNP) | VAF 68/209 reads (33%) | catalogued as COSV100200933; called by muse, mutect2, varscan2
- OR1A1 | c.732C>A p.L244= | Silent (SNP) | VAF 48/138 reads (35%) | catalogued as COSV100410715; called by muse, mutect2, varscan2
- OR2D2 | c.864T>C p.Y288= | Silent (SNP) | VAF 23/65 reads (35%) | catalogued as rs1488793538, COSV100203729; called by muse, mutect2, varscan2
- OR2L2 | c.327A>T p.A109= | Silent (SNP) | VAF 31/104 reads (30%) | catalogued as COSV100823179; called by muse, mutect2, varscan2
- OR5D18 | c.744C>T p.A248= | Silent (SNP) | VAF 20/65 reads (31%) | catalogued as rs765426060, COSV61736458; called by muse, mutect2, varscan2
- OR5F1 | c.621T>A p.I207= | Silent (SNP) | VAF 18/46 reads (39%) | catalogued as COSV99558401; called by muse, mutect2, varscan2
- OR5H2 | c.96G>T p.L32= | Silent (SNP) | VAF 67/198 reads (34%) | catalogued as rs753954499, COSV100788651; called by muse, mutect2, varscan2
- OR6K3 | c.861A>T p.T287= (on ENST00000368146; = p.T271= on NM_001005327.2) | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as COSV100933835; called by muse, mutect2, varscan2
- OR8U1 | c.60T>C p.H20= | Silent (SNP) | VAF 20/87 reads (23%) | catalogued as rs1188100488, COSV100163776; called by muse, mutect2, varscan2
- PCDHA1 | c.1497G>T p.V499= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV100974266; called by muse, mutect2, varscan2
- PCDHGB5 | c.1644G>T p.V548= | Silent (SNP) | VAF 11/25 reads (44%) | catalogued as rs1299146242; called by muse, mutect2, varscan2
- PDPK1 | c.1521G>A p.E507= | Silent (SNP) | VAF 33/87 reads (38%) | catalogued as rs1438283184, COSV99239116; called by muse, mutect2, varscan2
- POLR1B | c.129G>T p.V43= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs375042680, COSV99271031; called by muse, mutect2, varscan2
- PRR5L | c.972C>A p.L324= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV100286843; called by muse, mutect2, varscan2
- PTPN14 | c.2625G>T p.V875= | Silent (SNP) | VAF 25/58 reads (43%) | catalogued as rs1348024721, COSV100872364; called by muse, mutect2, varscan2
- PXDNL | c.3552G>T p.L1184= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV100681552; called by muse, mutect2
- RABGAP1L | c.1371G>T p.V457= | Silent (SNP) | VAF 20/71 reads (28%) | catalogued as COSV99268017; called by muse, mutect2, varscan2
- RMDN3 | c.36C>T p.A12= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs751606449, COSV99539861; called by muse, mutect2, varscan2
- RPS6KC1 | c.180A>T p.L60= | Silent (SNP) | VAF 33/116 reads (28%) | catalogued as COSV100873776; called by muse, mutect2, varscan2
- RTF1 | c.1884G>T p.V628= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV101047607; called by muse, mutect2, varscan2
- SLC35G3 | c.810G>T p.V270= | Silent (SNP) | VAF 29/107 reads (27%) | catalogued as rs139830119; called by muse, mutect2, varscan2
- SLC41A2 | c.582A>T p.T194= | Silent (SNP) | VAF 18/63 reads (29%) | catalogued as COSV99316185; called by muse, mutect2, varscan2
- SPATA31A1 | c.1008C>A p.A336= | Silent (SNP) | VAF 146/300 reads (49%) | called by muse, mutect2, varscan2
- SPDYA | c.744A>G p.L248= | Silent (SNP) | VAF 20/63 reads (32%) | catalogued as COSV100477822; called by muse, mutect2, varscan2
- SPTA1 | c.1686C>A p.A562= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV100934333; called by muse, mutect2, varscan2
- SREBF2 | c.1839G>T p.L613= | Silent (SNP) | VAF 28/53 reads (53%) | catalogued as COSV100761346; called by muse, mutect2, varscan2
- SYNE1 | c.25017C>A p.G8339= (on ENST00000367255 / NM_182961.4; = p.G8291= on NM_033071.3) | Silent (SNP) | VAF 36/95 reads (38%) | catalogued as COSV99554507; called by muse, mutect2
- TGM6 | c.243G>T p.R81= | Silent (SNP) | VAF 13/32 reads (41%) | catalogued as COSV99171683; called by muse, mutect2, varscan2
- TNR | c.1651C>A p.R551= | Silent (SNP) | VAF 17/53 reads (32%) | catalogued as rs200243334, COSV54917465, COSV99687753; called by muse, mutect2, varscan2
- TOGARAM1 | c.2607C>G p.V869= | Silent (SNP) | VAF 11/39 reads (28%) | catalogued as rs759371161, COSV100817836; called by muse, mutect2, varscan2
- VWC2 | c.744A>T p.L248= | Silent (SNP) | VAF 35/100 reads (35%) | catalogued as COSV61484421; called by muse, mutect2, varscan2
- ZNF334 | c.351G>T p.G117= | Silent (SNP) | VAF 30/83 reads (36%) | catalogued as COSV100748983; called by muse, mutect2, varscan2
- ZNF33B | c.816C>T p.D272= | Silent (SNP) | VAF 24/92 reads (26%) | catalogued as COSV100847597; called by muse, mutect2, varscan2
- AL590867.2 | n.370G>A | RNA (SNP) | VAF 29/84 reads (35%) | catalogued as rs1174432761; called by muse, mutect2, varscan2
- DCHS2 | n.2402C>T | RNA (SNP) | VAF 17/69 reads (25%) | catalogued as COSV100250942; called by muse, mutect2, varscan2
- DDHD1 | chr14:53152833 T>C | 5'Flank (SNP) | VAF 5/18 reads (28%) | catalogued as rs771632283, COSV100079080; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- EDN3 | c.588+21C>A | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as COSV100284796; called by muse, mutect2, varscan2
- KIR3DX1 | n.613C>G | RNA (SNP) | VAF 31/113 reads (27%) | catalogued as COSV99682972; called by muse, mutect2, varscan2
- LINC02872 | n.162G>T | RNA (SNP) | VAF 6/13 reads (46%) | called by muse, mutect2, varscan2
- PDE4B | c.477-199G>T | Intron (SNP) | VAF 23/83 reads (28%) | catalogued as rs1335648332, COSV100302337; called by muse, mutect2, varscan2
- POM121 | chr7:72949340 G>T | 3'Flank (SNP) | VAF 13/29 reads (45%) | catalogued as COSV99987655; called by muse, mutect2, varscan2
- RGS4 | chr1:163068972 G>T | 5'Flank (SNP) | VAF 4/17 reads (24%) | catalogued as COSV63357637; called by muse, mutect2
- STON2 | c.2784+46C>A | Intron (SNP) | VAF 36/107 reads (34%) | catalogued as COSV99964434; called by muse, mutect2, varscan2
